CCDI case PBBNVL — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Other and ill-defined sites.
https://portal.gdc.cancer.gov/cases/97a70db2-0978-4bc9-8bbc-8d59fe26477d

Demographics
Sex at birth: male; Ethnicity: hispanic or latino; Vital status: Alive.

Diagnoses (1)
1. Fibrosarcoma, NOS: ICD-O-3 morphology code: 8810/3; Tissue or organ of origin: Other ill-defined sites; Age at diagnosis: 19.4 years (7,082 days).

Biospecimens (2 samples)
- Sample 0DSI80: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DSI9D: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
